Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3JB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3JB-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY REPORT

1. "LESION RIGHT ARM STITCH PROXIMAL".

Immunohistochemical stains show the tumour has nuclear and cytoplasmic staining for S100, while is negative. This is consistent with melanoma.

SUPPLEMENTARY SUMMARY

1. Skin of right arm: METASTATIC MELANOMA.
2. Skin of posterior scalp: TRICHILEMMAL CYST.

REPORTED BY: Dr

ICD-0-3

Melanoma, NOS 8720/3
Site: subcutaneous tissue,
arm c49.1

hw
6/10/12

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Right upper arm melanoma (in-transit). Cyst on scalp.

MACROSCOPIC DESCRIPTION

(Dr

C-Note	Yes	No
I-PAA Discrepancy		

Two specimens received.

1. "LESION RIGHT ARM STITCH PROXIMAL". A skin ellipse 90 x 55 x 15mm, with suture on one tip denoted as 12 o'clock. On the surface there is a tan coloured nodular area 20 x 20 x 5mm. Specimen sectioned into fourteen slices from 12 o'clock to 6 o'clock. There is a subcutaneous white nodule in slices 6 to 11, 23 x 15 x 20mm. It has a central red area 5mm across (present in slice 10). The nodule appears to abut the deep margin in slice ten, and is well away from the lateral margins. Almost all of lesion embedded. Please refer to attached diagram.
Portion of tumour taken for melanoma tumour banking.

- A-C. Slice seven.
D. Slice eight (section used for tumour banking).
E-G. Slice ten. (Block F showing deepest margin).

2. "SEBACEOUS CYST POSTERIOR SCALP". A skin ellipse 40 x 20 x 20mm. The surface shows normal looking skin. Sectioning shows a white laminated nodule 25 x 15 x 20mm, abutting both deep and lateral margins. The nodule has a central area of calcification. Specimen sectioned into six slices. Nodule present in middle four slices. Almost all of nodule embedded.

2A

Two fins

[page 2 of 2]
Location:
Accession:

HISTOPATHOLOGY REPORT

2B-C. Representative sections of nodule.

MICROSCOPIC REPORT

1. "LESION RIGHT ARM STITCH PROXIMAL".

The sections of skin show several rounded deposits of metastatic melanoma in the dermis and subcutis. The melanoma is composed of sheets of pleomorphic epithelioid cells that lack melanin pigment. The mitotic rate is 20/mm². There is only a mild focal lymphocytic reaction to the melanoma. Excision appears complete with the deep margin clear by 2mm and the nearest lateral margin clear by at least 7mm.

2. "SEBACEOUS CYST POSTERIOR SCALP".

The sections of skin show a trichilemmal cyst (pilar cyst). No evidence of malignancy is seen. Excision appears complete.

SUMMARY

1. Skin of right arm: METASTATIC MELANOMA.

2. Skin of posterior scalp: TRICHILEMMAL CYST.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file b245abc5-f1ab-4810-9a06-f003184459be (TCGA-EE-A3JB.2F28F4E1-5B2E-4457-AA29-FE680DD0D75E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).